Somatic mutation profile of tumor specimen TCGA-EB-A299-01A (aliquot TCGA-EB-A299-01A-21D-A197-08) from TCGA case TCGA-EB-A299, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.9 years (23,322 days).
Specimen TCGA-EB-A299-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe4141b2-ce86-4708-a52e-e8a47ce2ae71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A299-10A (Blood Derived Normal), aliquot TCGA-EB-A299-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b7cf7ae-e746-4db2-b640-1ceaa6cda2de

The open-access MAF lists 183 somatic variants for this specimen: 114 protein-altering or splice-affecting, 64 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 64, Nonsense Mutation 11, Splice Site 3, RNA 3, Splice Region 2, 5'Flank 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/92 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CNGA1 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 28/127 reads (22%) | catalogued as rs567961453, CM153347, COSV62053210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPHP1 | c.1036C>T p.R346* (on ENST00000393272 / NM_207181.4; = p.R347* on NM_000272.5) | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as rs765263671, CM080456, COSV57206565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 15/68 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCC3 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.173); catalogued as COSV53317995; called by muse, mutect2, varscan2
- ADAM33 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62933835; called by muse, mutect2, varscan2
- AHRR | c.1694C>T p.T565I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV57083294; called by muse, mutect2, varscan2
- ANK1 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV55875103; called by muse, mutect2, varscan2
- ANKRD26 | c.4768G>A p.E1590K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV101062914; called by muse, mutect2, varscan2
- ANO2 | c.343C>T p.P115S (on ENST00000356134 / NM_001278597.3; = p.P119S on NM_001278596.3) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.108); catalogued as COSV100499735; called by muse, mutect2, varscan2
- API5 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV104430548, COSV66632527; called by muse, mutect2, varscan2
- API5 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV101124502; called by muse, varscan2
- B3GALT1 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs144099662, COSV59908175; called by muse, mutect2, varscan2
- BOLL | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.07); catalogued as COSV56573458; called by muse, mutect2
- BRD1 | c.64G>T p.V22F | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV53455241; called by muse, mutect2, varscan2
- BRINP3 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100818667, COSV66514204; called by muse, mutect2, varscan2
- C6 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54706408; called by muse, mutect2, varscan2
- CHAMP1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs376019121, COSV63521888; called by muse, mutect2, varscan2
- CHST4 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58296522; called by muse, mutect2, varscan2
- CIR1 | c.252+2T>C p.X84_splice | Splice Site (SNP) | VAF 17/62 reads (27%) | catalogued as COSV59595357; called by muse, mutect2, varscan2
- CLEC10A | c.533G>A p.G178E (on ENST00000254868 / NM_182906.4; = p.G154E on NM_006344.4) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV54700427; called by muse, mutect2, varscan2
- CNGB3 | c.1262T>A p.V421D | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV60685774; called by muse, mutect2, varscan2
- CNKSR1 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.139); catalogued as rs267598521, COSV64162915; called by muse, mutect2, varscan2
- CNTN4 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV61868939; called by muse, mutect2, varscan2
- CORO7 | c.2485C>T p.P829S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV52028475; called by muse, varscan2
- CSMD3 | c.7213G>A p.E2405K (on ENST00000297405 / NM_001363185.1; = p.E2301K on NM_052900.3) | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV52116824; called by muse, mutect2, varscan2
- CYP7A1 | c.408T>G p.H136Q | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56962596; called by muse, mutect2, varscan2
- DEUP1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV53210083; called by mutect2, varscan2
- DLG1 | c.2501C>T p.S834F (on ENST00000419354 / NM_001290983.1; = p.S856F on NM_004087.2) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs752360157, COSV58378749; called by muse, mutect2, varscan2
- DMBT1 | c.7399C>T p.R2467C (on ENST00000338354 / NM_001377530.1; = p.R1710C on NM_004406.3) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs763374104, COSV57536571; called by muse, varscan2
- DNAH3 | c.7492G>A p.D2498N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.661); catalogued as COSV54507262; called by muse, mutect2, varscan2
- DNAH5 | c.10129G>C p.E3377Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54208350, COSV54212780; called by muse, mutect2
- DNAH5 | c.9266C>T p.S3089L | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759831156, COSV54208359, COSV54225546; called by muse, mutect2, varscan2
- DNAJC12 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 86/200 reads (43%) | catalogued as COSV56546996; called by mutect2, varscan2
- EED | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV54553642; called by muse, mutect2
- EOMES | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV55411393; called by muse, varscan2
- ERBB4 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53508053; called by muse, mutect2, varscan2
- ESCO2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.118); catalogued as COSV59413469; called by muse, mutect2, varscan2
- F5 | c.5844G>A p.W1948* | Nonsense Mutation (SNP) | VAF 67/201 reads (33%) | catalogued as rs1286783795, COSV63121395; called by muse, mutect2, varscan2
- FAM131A | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.063); catalogued as COSV99658198; called by muse, mutect2, varscan2
- FAM214A | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV55922519; called by muse, mutect2, varscan2
- FAT4 | c.14796G>A p.W4932* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV58679814; called by muse, mutect2, varscan2
- GAS6 | c.1219G>C p.G407R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.149); catalogued as COSV59847876; called by muse, varscan2
- GLRA3 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV56857784; called by muse, mutect2, varscan2
- GOLGA3 | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.58); catalogued as COSV52626541; called by muse, mutect2, varscan2
- HS6ST3 | c.1240C>T p.L414F | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65002174; called by muse, mutect2, varscan2
- HSF5 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60415516, COSV60418195; called by muse, mutect2, varscan2
- ILDR2 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 64/239 reads (27%) | catalogued as COSV54828708; called by muse, varscan2
- IPO9 | c.2306C>T p.T769I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.2); catalogued as COSV64232947; called by muse, mutect2, varscan2
- KCNJ13 | c.139A>C p.I47L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52084834; called by muse, mutect2, varscan2
- KDM4D | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58633787; called by muse, mutect2, varscan2
- KERA | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.223); catalogued as COSV57130065; called by muse, mutect2, varscan2
- KLHL17 | c.1892C>T p.S631F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58531031; called by muse, mutect2, varscan2
- KMT5C | c.386G>A p.W129* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV55318546; called by muse, mutect2, varscan2
- LMTK3 | c.3606G>T p.R1202S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV54310204; called by mutect2, varscan2
- MECOM | c.2016C>T p.F672= (on ENST00000468789 / NM_001105078.4; = p.F860= on NM_004991.4) | Splice Region (SNP) | VAF 14/86 reads (16%) | catalogued as rs199555172, COSV52960674; called by muse, mutect2, varscan2
- MED16 | c.914T>A p.I305N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV99515111; called by muse, mutect2, varscan2
- MGAT4C | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59830487; called by muse, mutect2, varscan2
- MTIF2 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as COSV55050479; called by muse, mutect2, varscan2
- MUC16 | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.053); catalogued as COSV67449814; called by muse, mutect2, varscan2
- MYH2 | c.2770A>G p.K924E | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV99819224; called by muse, mutect2, varscan2
- NHLRC2 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100800208, COSV63749603; called by muse, mutect2, varscan2
- NLRP12 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV60744235; called by muse, mutect2, varscan2
- NUDT15 | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.993); catalogued as COSV99320220; called by muse, mutect2, varscan2
- OR2D3 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53491951; called by muse, mutect2, varscan2
- OR2V2 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV60314842; called by mutect2, varscan2
- OR8D1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV63441764; called by muse, mutect2, varscan2
- OSM | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV53160869; called by muse, mutect2, varscan2
- OTX1 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56993852; called by muse, mutect2, varscan2
- PCDH18 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs777279874, COSV61266746; called by muse, mutect2, varscan2
- PCDHB9 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV53376065; called by mutect2, varscan2
- PCDHGB2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53909216; called by muse, mutect2, varscan2
- PDE6C | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65114990; called by muse, mutect2, varscan2
- PKHD1 | c.3847T>C p.S1283P | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV61863579; called by muse, mutect2, varscan2
- PKHD1L1 | c.1888G>T p.G630* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV65738679, COSV65747198; called by mutect2, varscan2
- PLK3 | c.1552G>A p.V518M | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs770268851, COSV59499210; called by mutect2, varscan2
- PRAMEF1 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 100/275 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1413516209, COSV60006660; called by muse, mutect2, varscan2
- PRRC2B | c.3229C>T p.R1077C | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776283820, COSV61934390; called by mutect2, varscan2
- PSG3 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166787788, COSV59502843; called by muse, mutect2, varscan2
- RBMXL2 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as rs1259113210, COSV60978794; called by muse, varscan2
- RXFP3 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57504359; called by muse, mutect2, varscan2
- RYR2 | c.11320C>T p.Q3774* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100767697; called by mutect2, varscan2
- SDCBP | c.654A>G p.I218M | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50684327; called by muse, mutect2
- SI | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV52268530, COSV52276596; called by muse, mutect2, varscan2
- SLC8A3 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.899); catalogued as COSV63519449; called by muse, mutect2, varscan2
- SLX4 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.514); catalogued as rs1245512542, COSV53561404; called by muse, mutect2, varscan2
- SNCAIP | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs867274068, COSV54403663; called by muse, mutect2, varscan2
- SPATA19 | c.278A>C p.H93P | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV54482701; called by muse, mutect2
- SPHKAP | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV60870653; called by muse, mutect2, varscan2
- SPTB | c.6427G>A p.G2143R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61551949; called by muse, mutect2, varscan2
- TBC1D17 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99680380; called by muse, mutect2, varscan2
- TEX2 | c.3281A>C p.N1094T (on ENST00000583097 / NM_001288733.2; = p.N1101T on NM_018469.5) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51978070; called by muse, mutect2, varscan2
- TMEM177 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 52/145 reads (36%) | catalogued as COSV55608199; called by muse, mutect2, varscan2
- TMEM59L | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as rs781662682, COSV53241615; called by muse, mutect2, varscan2
- TPP2 | c.2992A>T p.T998S | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV101060166; called by muse, mutect2, varscan2
- TPP2 | c.2993C>T p.T998I | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101060167; called by muse, mutect2, varscan2
- TRPS1 | c.3149G>A p.G1050E (on ENST00000220888 / NM_001330599.2; = p.G1063E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs776955806, COSV55229155, COSV99630260; called by muse, mutect2, varscan2
- TULP1 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs866341403, COSV57692073; called by muse, mutect2, varscan2
- UBR4 | c.12260C>T p.P4087L | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as COSV64383741; called by muse, mutect2, varscan2
- USP31 | c.2278C>T p.L760F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV54849883; called by muse, varscan2
- VIP | c.231-1G>A p.X77_splice | Splice Site (SNP) | VAF 26/54 reads (48%) | catalogued as COSV65888597; called by muse, mutect2, varscan2
- XDH | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1344872094, COSV65147294; called by muse, mutect2, varscan2
- XIRP2 | c.5182G>A p.E1728K (on ENST00000628543; = p.E1903K on NM_152381.6) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54686025; called by muse, mutect2, varscan2
- ZFHX4 | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV50552855; called by muse, mutect2, varscan2
- ZMIZ2 | c.814-1G>A p.X272_splice | Splice Site (SNP) | VAF 56/211 reads (27%) | catalogued as rs1263247298, COSV54806304; called by muse, mutect2, varscan2
- ZMYM4 | c.2125C>T p.Q709* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV58907587; called by muse, mutect2, varscan2
- ZNF225 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as COSV53471010; called by muse, mutect2, varscan2
- ZNF625 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.767); catalogued as COSV63241364; called by muse, mutect2, varscan2
- ZNF827 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV101061139; called by muse, mutect2, varscan2
- DCP1A | c.807dup p.Q270Sfs*18 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- FAM21FP | n.997G>C | Splice Region (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- PRAMEF17 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- TRBV24-1 | c.325T>C p.F109L | Missense Mutation (SNP) | VAF 77/108 reads (71%) | SIFT tolerated (0.67); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AMIGO1 | c.474C>T p.A158= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV63990267; called by muse, mutect2, varscan2
- ANKRD26 | c.4767G>A p.V1589= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV101062915; called by muse, mutect2, varscan2
- APOB | c.3984C>T p.F1328= | Silent (SNP) | VAF 142/433 reads (33%) | catalogued as COSV51923358; called by muse, mutect2, varscan2
- ARHGAP31 | c.1371G>A p.S457= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs753753846, COSV51789804, COSV51794480; called by muse, varscan2
- BDKRB2 | c.873C>T p.F291= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV60013842; called by muse, mutect2, varscan2
- CACNA1A | c.3495G>A p.R1165= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs772768681, COSV64191602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN6 | c.2364C>T p.S788= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV63163956; called by muse, varscan2
- CSF2RA | c.60G>A p.L20= | Silent (SNP) | VAF 105/312 reads (34%) | catalogued as COSV62623454; called by muse, mutect2, varscan2
- CSMD2 | c.3333C>T p.S1111= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1202589422, COSV53886053; called by mutect2, varscan2
- DAZAP1 | c.1131C>T p.S377= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs766812291, COSV51831543; called by mutect2, varscan2
- DBX2 | c.816C>T p.F272= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV60336483; called by muse, mutect2, varscan2
- DNAH7 | c.11025C>T p.F3675= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs928283991, COSV56754428, COSV56774686; called by mutect2, varscan2
- DSG1 | c.162C>T p.F54= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs778383508, COSV57133722; called by muse, mutect2, varscan2
- EFHC1 | c.1557C>T p.N519= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs773385237, COSV64135593; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- FMO1 | c.1116C>T p.I372= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV61444838; called by muse, mutect2, varscan2
- GPR141 | c.309C>T p.F103= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV57731485, COSV57731837; called by muse, mutect2, varscan2
- GPR161 | c.1095C>T p.I365= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV54788271; called by muse, varscan2
- GPR179 | c.6738G>A p.E2246= (on ENST00000621958; = p.E2245= on NM_001004334.4) | Silent (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- GTF2H4 | c.987C>T p.A329= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV52558016; called by muse, mutect2, varscan2
- HYDIN | c.14937C>T p.G4979= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV66637623; called by muse, mutect2, varscan2
- IL17REL | c.153C>T p.T51= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV58007752; called by muse, mutect2, varscan2
- IRX4 | c.528C>T p.I176= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV51471048; called by mutect2, varscan2
- KNDC1 | c.4128G>A p.E1376= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1288676946, COSV58832211; called by muse, varscan2
- LRP1 | c.4752C>T p.F1584= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV54503664; called by muse, varscan2
- LRP2 | c.10320T>C p.N3440= | Silent (SNP) | VAF 24/278 reads (9%) | catalogued as COSV55543609; called by muse, mutect2
- LYST | c.6639A>C p.S2213= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV67704036; called by muse, mutect2, varscan2
- MAGEB1 | c.990G>A p.T330= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as rs1361369413, COSV66775315, COSV66775324; called by mutect2, varscan2
- MYO18B | c.7086G>A p.G2362= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV59127325; called by muse, mutect2, varscan2
- NCOR2 | c.4290C>T p.R1430= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs371027420; called by mutect2, varscan2
- NEB | c.11526C>T p.Y3842= | Silent (SNP) | VAF 10/135 reads (7%) | catalogued as COSV50832412; called by muse, mutect2
- NLGN4X | c.1866C>T p.P622= | Silent (SNP) | VAF 37/59 reads (63%) | catalogued as rs947170788, COSV52007287, COSV99320518; called by muse, mutect2, varscan2
- NLGN4Y | c.1866C>T p.P622= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV59294492; called by muse, mutect2, varscan2
- NOP14 | c.1998C>T p.L666= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV58624175; called by muse, mutect2, varscan2
- NR1D2 | c.183C>T p.A61= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV56990915; called by muse, mutect2, varscan2
- OR10A5 | c.879G>A p.L293= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV55053363; called by mutect2, varscan2
- OR10R2 | c.897G>A p.T299= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as rs146808200; called by muse, mutect2, varscan2
- OR1S2 | c.822C>T p.F274= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV56918572; called by muse, mutect2, varscan2
- OR2B11 | c.813C>T p.S271= | Silent (SNP) | VAF 50/135 reads (37%) | catalogued as COSV59509470, COSV59509888; called by muse, mutect2, varscan2
- PCDHA12 | c.1791G>A p.V597= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV56481949; called by muse, mutect2, varscan2
- PDCL3 | c.198G>A p.E66= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV51808781; called by muse, mutect2
- PITRM1 | c.1749C>A p.I583= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs776153053, COSV56527279; called by muse, mutect2, varscan2
- PNLIPRP1 | c.378G>A p.K126= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV62610978; called by muse, mutect2, varscan2
- PPARA | c.1030C>T p.L344= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV53077331; called by muse, mutect2, varscan2
- PRSS1 | c.240C>T p.V80= | Silent (SNP) | VAF 93/166 reads (56%) | catalogued as rs772622287, COSV61191008; ClinVar: likely benign; called by muse, mutect2, varscan2
- RHBDL1 | c.210C>T p.A70= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs773079364, COSV54802526; called by muse, mutect2
- RPGRIP1 | c.1827C>T p.A609= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV52845857; called by muse, mutect2, varscan2
- RSPO4 | c.276G>A p.G92= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs1555795575, COSV54080730; called by muse, mutect2, varscan2
- RYR2 | c.11319A>G p.V3773= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100767112; called by muse, mutect2, varscan2
- SHANK2 | c.2511G>A p.L837= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV53588152; called by muse, mutect2, varscan2
- SLC22A12 | c.63G>A p.T21= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as rs762500419, COSV60571136; called by muse, mutect2, varscan2
- SMAD7 | c.693C>T p.S231= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV50988855; called by muse, mutect2, varscan2
- SON | c.7233T>C p.N2411= | Silent (SNP) | VAF 11/82 reads (13%) | called by mutect2, varscan2
- STAB2 | c.1812C>T p.S604= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs748463325, COSV66335374; called by muse, mutect2, varscan2
- TAF4 | c.2895C>T p.I965= | Silent (SNP) | VAF 73/274 reads (27%) | catalogued as COSV53335108; called by muse, mutect2, varscan2
- TBC1D17 | c.651G>A p.Q217= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV55579476; called by muse, mutect2, varscan2
- TFR2 | c.2316C>T p.F772= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV56153255, COSV56156173; called by muse, mutect2, varscan2
- TMCC1 | c.1113G>A p.E371= (on ENST00000393238 / NM_001349268.2; = p.E47= on NM_015008.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100260702; called by muse, mutect2, varscan2
- TP53 | c.741C>T p.N247= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs786202448, COSV52772996, COSV52808615, COSV52847658; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRIML2 | c.1119C>T p.F373= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as COSV58714865; called by muse, mutect2, varscan2
- UPK1A | c.522C>T p.A174= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV55877564; called by muse, mutect2, varscan2
- ZNF208 | c.2205C>T p.V735= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV68101694; called by muse, varscan2
- ZNF285 | c.273C>T p.I91= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs200246187, COSV58408188; called by muse, mutect2, varscan2
- ZNF618 | c.1818C>T p.F606= (on ENST00000374126 / NM_001318042.2; = p.F513= on NM_133374.2) | Silent (SNP) | VAF 38/65 reads (58%) | catalogued as rs369421645; called by mutect2, varscan2
- ZNF827 | c.267G>A p.E89= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV101061142; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918810 C>T | 5'Flank (SNP) | VAF 9/26 reads (35%) | catalogued as rs570433496, COSV100711419, COSV62704012; called by muse, mutect2, varscan2
- C8orf86 | n.953C>T | RNA (SNP) | VAF 26/92 reads (28%) | catalogued as rs138372010, COSV63935145; called by muse, mutect2, varscan2
- FBXL21P | n.534G>A | RNA (SNP) | VAF 41/100 reads (41%) | catalogued as COSV51808342; called by muse, mutect2, varscan2
- RGS3 | c.3081-350C>T | Intron (SNP) | VAF 43/83 reads (52%) | catalogued as COSV100636554; called by muse, mutect2, varscan2
- RNF217-AS1 | n.3144G>A | RNA (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
